Somatic mutation profile of tumor specimen TCGA-B9-4113-01A (aliquot TCGA-B9-4113-01A-01D-1252-08) from TCGA case TCGA-B9-4113, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 64.6 years (23,613 days).
Specimen TCGA-B9-4113-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3a4ad42-40e5-4471-a65c-b9157679a88e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-4113-11A (Solid Tissue Normal), aliquot TCGA-B9-4113-11A-01D-1252-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abeb970e-224a-4c15-8505-854f1ffdaee0

The open-access MAF lists 74 somatic variants for this specimen: 57 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 37, Silent 17, Frame Shift Del 7, Nonsense Mutation 5, Splice Site 4, Frame Shift Ins 2, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASDH | c.326T>A p.I109N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV52704882; called by muse, mutect2, varscan2
- ACAD10 | c.2251C>A p.P751T | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV58155006; called by muse, mutect2, varscan2
- ACOX3 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1189806833, COSV62711288; called by muse, mutect2, varscan2
- ADGRA3 | c.3045G>C p.L1015F | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV51561048; called by muse, mutect2, varscan2
- AGTPBP1 | c.3003A>T p.Q1001H (on ENST00000357081 / NM_001330701.2; = p.Q961H on NM_015239.2) | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV61269707; called by muse, mutect2, varscan2
- ATAD5 | c.4857T>G p.N1619K | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV58972824; called by muse, mutect2, varscan2
- CA9 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 23/84 reads (27%) | catalogued as COSV65675158; called by muse, mutect2, varscan2
- CD46 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59731933; called by muse, mutect2, varscan2
- CGNL1 | c.641C>G p.T214R | Missense Mutation (SNP) | VAF 158/439 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV55564915; called by muse, mutect2, varscan2
- COX15 | c.16T>G p.F6V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV99187613; called by muse, mutect2, varscan2
- DHDH | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1316123138, COSV55481727; called by muse, mutect2, varscan2
- DOT1L | c.365C>G p.P122R | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67108574, COSV67109183; called by muse, mutect2, varscan2
- E2F8 | c.1619T>A p.L540Q | Missense Mutation (SNP) | VAF 142/389 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as COSV51462405; called by muse, mutect2, varscan2
- ECD | c.1680A>C p.K560N | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV61968312; called by muse, mutect2, varscan2
- FAM149A | c.1289A>G p.Q430R (on ENST00000356371 / NM_001367768.2; = p.Q139R on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1383841536, COSV57026300; called by muse, mutect2, varscan2
- HAAO | c.850C>G p.P284A | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54310170; called by muse, mutect2, varscan2
- HADHA | c.216C>G p.F72L | Missense Mutation (SNP) | VAF 81/239 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV66106676, COSV66109062; called by muse, mutect2, varscan2
- HELZ2 | c.6703A>G p.R2235G (on ENST00000467148 / NM_001037335.2; = p.R1666G on NM_033405.3) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV71295594; called by muse, mutect2, varscan2
- LIFR | c.1330A>G p.I444V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV54686391; called by muse, mutect2, varscan2
- LSS | c.1468-2A>C p.X490_splice | Splice Site (SNP) | VAF 56/139 reads (40%) | catalogued as COSV62700297; called by muse, mutect2, varscan2
- MADD | c.1667T>G p.L556R | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60621696; called by muse, mutect2, varscan2
- MCOLN3 | c.1191G>T p.K397N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV62013405; called by muse, mutect2, varscan2
- NWD1 | c.4045G>A p.E1349K | Missense Mutation (SNP) | VAF 142/381 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as rs770385137, COSV60339236; called by muse, mutect2, varscan2
- OBI1 | c.1390A>T p.T464S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56144938; called by muse, mutect2, varscan2
- OR11A1 | c.38A>C p.E13A | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV65820788; called by muse, mutect2, varscan2
- ORC2 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52237666; called by muse, mutect2, varscan2
- OSBPL10 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 82/280 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV67337371; called by muse, mutect2, varscan2
- PDZRN4 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 31/99 reads (31%) | catalogued as COSV68402795; called by muse, mutect2, varscan2
- PIGR | c.1903G>T p.G635* | Nonsense Mutation (SNP) | VAF 67/159 reads (42%) | catalogued as COSV62903511; called by muse, mutect2, varscan2
- PIK3C2G | c.3220G>A p.D1074N (on ENST00000676171; = p.D1033N on NM_004570.5) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56802047; called by muse, mutect2, varscan2
- PPP1R12A | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs1210060972; called by muse, varscan2
- PRKRIP1 | c.306G>A p.K102= | Splice Region (SNP) | VAF 129/341 reads (38%) | catalogued as COSV61349595; called by muse, mutect2, varscan2
- PRKRIP1 | c.306+1G>A p.X102_splice | Splice Site (SNP) | VAF 131/339 reads (39%) | catalogued as rs781815142, COSV61349602; called by muse, mutect2, varscan2
- QSER1 | c.1739C>A p.S580* (on ENST00000399302; = p.S709* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV67899868; called by muse, mutect2, varscan2
- RBM34 | c.548A>T p.N183I | Missense Mutation (SNP) | VAF 84/246 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV64012504; called by muse, mutect2, varscan2
- RGS14 | c.1218G>T p.K406N | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV68771002; called by muse, varscan2
- SALL3 | c.2981T>C p.I994T | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV73305870; called by muse, mutect2, varscan2
- SLC16A6 | c.233-1G>T p.X78_splice | Splice Site (SNP) | VAF 44/99 reads (44%) | catalogued as COSV59176600; called by muse, mutect2, varscan2
- SLC26A1 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1338277890, COSV56101993; called by muse, mutect2, varscan2
- SLC36A3 | c.1002C>A p.Y334* | Nonsense Mutation (SNP) | VAF 68/184 reads (37%) | catalogued as COSV58856209; called by muse, mutect2, varscan2
- SLC46A3 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV57180752; called by muse, mutect2, varscan2
- TANC2 | c.2791C>A p.L931M | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.129); catalogued as COSV67332007; called by muse, mutect2, varscan2
- TRNT1 | c.1118G>C p.C373S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV51640208; called by muse, mutect2, varscan2
- UBR4 | c.4722G>C p.K1574N | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV64384783; called by muse, mutect2, varscan2
- ZNF136 | c.438G>T p.W146C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV59710398; called by muse, mutect2, varscan2
- ZNF665 | c.178G>C p.A60P (on ENST00000600412; = p.A125P on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV67214095; called by muse, mutect2, varscan2
- A2ML1 | c.2605del p.T869Lfs*126 | Frame Shift Del (DEL) | VAF 66/149 reads (44%) | called by mutect2, pindel, varscan2
- ANTXR1 | c.1654_1657del p.A552Lfs*41 | Frame Shift Del (DEL) | VAF 36/97 reads (37%) | called by mutect2, pindel, varscan2
- COL5A1 | c.521del p.K174Rfs*6 | Frame Shift Del (DEL) | VAF 26/77 reads (34%) | called by mutect2, pindel, varscan2
- CYP2D6 | c.1106_1115del p.I369Rfs*3 | Frame Shift Del (DEL) | VAF 18/158 reads (11%) | called by mutect2, pindel
- GTF3C2 | c.342_343insA p.Q115Tfs*4 | Frame Shift Ins (INS) | VAF 92/238 reads (39%) | called by mutect2, varscan2*
- HECA | c.1382del p.K461Sfs*32 | Frame Shift Del (DEL) | VAF 53/184 reads (29%) | called by mutect2, pindel, varscan2
- PTPRM | c.32del p.L11Wfs*6 | Frame Shift Del (DEL) | VAF 36/104 reads (35%) | called by mutect2, pindel*, varscan2
- ST20 | c.46-7_46-2del p.X16_splice | Splice Site (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel
- TOP3B | c.863_865dup p.T288dup | In Frame Ins (INS) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- XRCC5 | c.318dup p.F107Lfs*15 | Frame Shift Ins (INS) | VAF 25/80 reads (31%) | called by mutect2, pindel, varscan2
- ZMYM6 | c.2019del p.K673Nfs*14 | Frame Shift Del (DEL) | VAF 45/163 reads (28%) | called by mutect2, pindel, varscan2
- ABCG2 | c.775T>C p.L259= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV52944328; called by muse, mutect2, varscan2
- ASB5 | c.945A>G p.Q315= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV56669351; called by muse, mutect2, varscan2
- ATP7B | c.1248T>A p.A416= | Silent (SNP) | VAF 80/226 reads (35%) | catalogued as COSV54436411; called by muse, mutect2, varscan2
- ATR | c.2268T>A p.S756= | Silent (SNP) | VAF 46/135 reads (34%) | catalogued as COSV63385016; called by muse, mutect2, varscan2
- CASP14 | c.267C>T p.H89= | Silent (SNP) | VAF 35/230 reads (15%) | catalogued as rs1408672307, COSV55665040, COSV99693121; called by muse, mutect2, varscan2
- DOT1L | c.2355G>A p.L785= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as rs377506676; called by muse, mutect2, varscan2
- EDAR | c.675G>A p.P225= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as rs746044070, COSV51500795; ClinVar: likely benign; called by muse, mutect2, varscan2
- EML4 | c.498T>C p.A166= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV59295199; called by muse, mutect2, varscan2
- EPHA8 | c.2421A>T p.P807= | Silent (SNP) | VAF 79/201 reads (39%) | catalogued as COSV51264517; called by muse, mutect2, varscan2
- MCTP2 | c.240C>T p.S80= | Silent (SNP) | VAF 76/256 reads (30%) | catalogued as COSV59142120; called by muse, mutect2, varscan2
- MTOR | c.3138C>G p.T1046= | Silent (SNP) | VAF 67/172 reads (39%) | catalogued as COSV63869338; called by muse, mutect2, varscan2
- NDST4 | c.2076C>T p.I692= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as COSV52112548; called by muse, mutect2, varscan2
- SPINT1 | c.855C>T p.G285= | Silent (SNP) | VAF 104/309 reads (34%) | catalogued as COSV59801402; called by muse, mutect2, varscan2
- SQSTM1 | c.132C>T p.C44= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs11548639; called by muse, varscan2
- TMEM132D | c.504G>C p.L168= | Silent (SNP) | VAF 50/85 reads (59%) | catalogued as COSV70598243; called by muse, mutect2, varscan2
- TP53BP1 | c.3651C>T p.L1217= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV55497984; called by muse, mutect2, varscan2
- ZNF777 | c.1920G>A p.E640= | Silent (SNP) | VAF 210/564 reads (37%) | catalogued as COSV56096662; called by muse, mutect2, varscan2
